Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A0XF, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A0XF-01A (Primary Tumor).

TSS Patient ID: Sample Procurement: Date:

Gender:
Vital Status: Deceased

Date of Birth:
Date of Death:

Race: White Ethnicity: Not Hispanic or Latino Specific Ethnicity:

Histologic Subtype: Colon adenocarcinoma Date of Initial Path Dx:
Primary Site: Colons Anatomic Site: Sigmoid Colon
T Stage: 3 N Stage: 1 M Stage: 1 Overall Stage: IV

Date of Normal Procurement:

ICD-O-3
adenocarcinoma, NOS 8140/3
Site: sigmoid colon C18.7

lw
6/11/12

Source: NCI Genomic Data Commons file 0935bed0-b479-4927-ba9e-7e13ca1d3e21 (TCGA-DM-A0XF.2E442714-A485-48C1-80FD-9418ABD94D9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).